Somatic mutation profile of tumor specimen C3N-03921-02 (aliquot CPT0223260006) from CPTAC case C3N-03921, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 73.1 years (26,682 days).
Specimen C3N-03921-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cc0c503-d318-4ba5-83a6-517de543f69e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03921-71 (Blood Derived Normal), aliquot CPT0223370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3deb9387-b3c0-4b98-9fa8-231961a909da

The open-access MAF lists 76 somatic variants for this specimen: 46 protein-altering or splice-affecting, 19 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 19, Intron 9, Nonsense Mutation 3, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 1, Splice Site 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 105/432 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 151/415 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 231/606 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 80/252 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRV1 | c.10214G>T p.R3405L | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV67985287, COSV67992259; called by mutect2, varscan2
- ANKS1B | c.2015C>A p.T672K | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754688070; called by muse, mutect2, varscan2
- CLCN7 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 82/800 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs758953225; called by muse, varscan2
- CNTNAP4 | c.486G>T p.W162C | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56666710; called by muse, mutect2, varscan2
- DNAH9 | c.6866C>T p.P2289L | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs773384248, COSV52343191; called by muse, mutect2, varscan2
- EYA4 | c.985C>G p.P329A | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs375169460; called by muse, mutect2, varscan2
- FLG | c.2504A>C p.Q835P | Missense Mutation (SNP) | VAF 147/584 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs376730337; called by muse, mutect2, varscan2
- FLNA | c.7324G>A p.G2442S (on ENST00000369850 / NM_001110556.2; = p.G2434S on NM_001456.3) | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.908); catalogued as rs782189345; called by muse, mutect2
- PHEX | c.759G>T p.M253I | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV101039823; called by muse, mutect2
- SERPINA5 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 77/532 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.149); catalogued as rs368796795, COSV61573577; called by muse, mutect2, varscan2
- TENT5B | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56693650; called by muse, mutect2, varscan2
- TXLNB | c.1257G>T p.M419I | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759525871, COSV100624795, COSV100624859; called by muse, mutect2, varscan2
- WNT8A | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs755478873, COSV64230854; called by muse, mutect2, varscan2
- ADAM33 | c.1134-8G>T | Splice Region (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- AGMO | c.818T>A p.V273E | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ARMC2 | c.2240A>T p.D747V | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CCDC6 | c.474A>C p.E158D | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- CLINT1 | c.621_622del p.K207Nfs*6 | Frame Shift Del (DEL) | VAF 22/180 reads (12%) | called by mutect2, pindel, varscan2
- COL1A2 | c.2200C>A p.Q734K | Missense Mutation (SNP) | VAF 103/893 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CRYBG3 | c.271G>C p.V91L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, varscan2
- CSMD1 | c.10206C>A p.G3402= (on ENST00000520002; = p.G3401= on NM_033225.6) | Splice Region (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- DHRS1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 90/407 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- EBF2 | c.1054A>T p.K352* | Nonsense Mutation (SNP) | VAF 11/167 reads (7%) | called by muse, mutect2
- FANCB | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 28/162 reads (17%) | called by muse, mutect2, varscan2
- FARS2 | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 140/479 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FIG4 | c.1750+2T>C p.X584_splice | Splice Site (SNP) | VAF 20/142 reads (14%) | called by muse, mutect2, varscan2
- FLNA | c.1069A>G p.T357A | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- GABBR1 | c.2319C>G p.F773L | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- GLUL | c.950C>G p.A317G | Missense Mutation (SNP) | VAF 122/543 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GOSR2 | c.410T>C p.V137A (on ENST00000393456 / NM_001321134.1; = p.V202A on NM_004287.5) | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HACE1 | c.1363G>C p.V455L | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KIAA1217 | c.2497C>G p.Q833E | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- N4BP2 | c.2008C>G p.P670A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- NQO1 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 15/263 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PSD4 | c.1457A>G p.D486G | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SGCB | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A53 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2
- SOBP | c.1933G>A p.V645M | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- SRFBP1 | c.936dup p.V313Sfs*4 | Frame Shift Ins (INS) | VAF 12/119 reads (10%) | called by mutect2, pindel, varscan2
- TCEA3 | c.481dup p.T161Nfs*3 | Frame Shift Ins (INS) | VAF 33/301 reads (11%) | called by mutect2, pindel, varscan2
- TNFAIP6 | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK4 | c.2642G>A p.W881* | Nonsense Mutation (SNP) | VAF 87/576 reads (15%) | called by muse, mutect2, varscan2
- ADRA2C | c.807C>A p.G269= | Silent (SNP) | VAF 38/175 reads (22%) | called by muse, mutect2, varscan2
- AR | c.1014A>G p.T338= | Silent (SNP) | VAF 24/164 reads (15%) | called by muse, mutect2, varscan2
- BMP8B | c.831C>T p.N277= | Silent (SNP) | VAF 64/908 reads (7%) | catalogued as rs377450201; called by muse, mutect2
- CFAP74 | c.1431C>T p.P477= | Silent (SNP) | VAF 59/207 reads (29%) | catalogued as rs1287877837, COSV54564673; called by muse, mutect2, varscan2
- CPXM2 | c.1389C>G p.L463= | Silent (SNP) | VAF 21/210 reads (10%) | catalogued as rs762881077, COSV53868678; called by muse, mutect2, varscan2
- DNAH9 | c.381G>A p.A127= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs1484287727; called by muse, mutect2, varscan2
- FARS2 | c.93C>G p.A31= | Silent (SNP) | VAF 57/277 reads (21%) | called by muse, mutect2, varscan2
- IGDCC3 | c.1908G>T p.T636= | Silent (SNP) | VAF 51/229 reads (22%) | catalogued as COSV60076831; called by muse, mutect2, varscan2
- KCNJ9 | c.243G>A p.L81= | Silent (SNP) | VAF 46/266 reads (17%) | catalogued as COSV100927810; called by muse, mutect2, varscan2
- LAMB4 | c.4944G>A p.A1648= | Silent (SNP) | VAF 36/290 reads (12%) | catalogued as rs746739880; called by muse, mutect2, varscan2
- MTUS2 | c.1443G>A p.T481= | Silent (SNP) | VAF 40/164 reads (24%) | catalogued as rs201515125; called by muse, mutect2, varscan2
- MYT1L | c.1215T>C p.C405= | Silent (SNP) | VAF 13/367 reads (4%) | called by muse, mutect2
- NMT2 | c.1260C>T p.A420= | Silent (SNP) | VAF 20/150 reads (13%) | catalogued as rs768580307; called by muse, mutect2, varscan2
- PCDHGB6 | c.1338C>T p.N446= | Silent (SNP) | VAF 42/327 reads (13%) | catalogued as COSV53988870; called by muse, mutect2, varscan2
- PEX26 | c.129C>T p.D43= | Silent (SNP) | VAF 45/202 reads (22%) | called by muse, mutect2, varscan2
- PIEZO2 | c.6792C>G p.V2264= | Silent (SNP) | VAF 53/363 reads (15%) | called by muse, mutect2, varscan2
- PKIB | c.219T>C p.P73= | Silent (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2, varscan2
- PNPLA8 | c.1089C>A p.T363= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV57553665; called by muse, mutect2, varscan2
- ZNF831 | c.453C>T p.R151= | Silent (SNP) | VAF 25/336 reads (7%) | catalogued as rs778350290, COSV64038516, COSV64041752; called by muse, mutect2
- ADAM6 | n.1548G>T | RNA (SNP) | VAF 25/138 reads (18%) | called by muse, mutect2, varscan2
- CADM2 | c.62-75553T>G | Intron (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- DSG1 | c.1821+37C>A | Intron (SNP) | VAF 46/306 reads (15%) | called by muse, mutect2, varscan2
- EIF2B5 | c.1180+9A>G | Intron (SNP) | VAF 51/220 reads (23%) | called by muse, mutect2, varscan2
- HPS5 | c.1510+27C>T | Intron (SNP) | VAF 76/266 reads (29%) | called by muse, mutect2, varscan2
- HPS5 | c.1510+26C>T | Intron (SNP) | VAF 76/266 reads (29%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4397G>A | Intron (SNP) | VAF 48/421 reads (11%) | catalogued as rs868966696, COSV56539496; called by muse, mutect2, varscan2
- PPP1R36 | c.-7C>T | 5'UTR (SNP) | VAF 44/296 reads (15%) | catalogued as COSV100072856; called by muse, mutect2, varscan2
- PTPMT1 | c.174+13G>T | Intron (SNP) | VAF 27/186 reads (15%) | called by muse, mutect2, varscan2
- WDR13 | c.41+42T>C | Intron (SNP) | VAF 20/208 reads (10%) | catalogued as rs1367313928; called by muse, mutect2
- ZNF783 | c.803-2118del | Intron (DEL) | VAF 42/162 reads (26%) | called by mutect2, pindel, varscan2
